Gene-level copy-number profile of tumor specimen ALCH-B0BU-TTP1-A from ALCHEMIST case ALCH-B0BU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.7 years (22,159 days).
Specimen ALCH-B0BU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09bcb835-9ef1-4004-9acb-ce26e33f76f2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0BU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/e3aa5e82-a8f1-4340-b2a1-c3e7addca412

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 713; copy number 2: 55,810; copy number 3: 1,261; copy number 4: 301; copy number 5: 52; copy number 6: 107; copy number 7: 125; copy number 8: 18; copy number 9: 3; copy number 19: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 306 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:159,448,556–161,549,044, 26 genes, copy number 6 (within-gene range 2–6): LINC01845, LINC01847, ADRA1B, GAPDHP40, Y_RNA, TTC1, AC068657.1, PWWP2A, FABP6, FABP6-AS1, AC112191.1, CCNJL, AC112191.2, AC112191.3, C1QTNF2, ZBED8, SLU7, PTTG1, MIR3142HG, MIR3142, MIR146A, ATP10B, AC008456.1, AC011363.1, LINC02159, GABRB2.
- chr11:1,947,278–1,989,920, 2 genes, copy number 19: MRPL23, MRPL23-AS1.
- chr12:51,590,266–51,997,078, 11 genes, copy number 5 (within-gene range 2–5): SCN8A, HNRNPA3P10, AC068987.1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B.
- chr12:53,935,328–53,977,643, 9 genes, copy number 6: HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11.
- chr12:57,674,665–58,244,865, 32 genes, copy number 7: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr12:66,347,431–67,069,162, 3 genes, copy number 9 (within-gene range 2–9): GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:68,842,197–68,971,570, 1 gene, copy number 5 (within-gene range 4–6): CPM.
- chr12:68,957,377–71,118,247, 40 genes, copy number 5–6: PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr19:35,042,902–35,285,143, 18 genes, copy number 8 (within-gene range 3–8): HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP.
- chr19:35,596,581–35,869,287, 27 genes, copy number 7 (within-gene range 2–7): LINC01766, AC002115.1, HAUS5, RBM42, ETV2, COX6B1, UPK1A, UPK1A-AS1, TYMSP2, ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6, PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2, NPHS1, KIRREL2.
- chr19:35,935,358–36,173,853, 21 genes, copy number 6: LRFN3, AF038458.3, AF038458.1, AF038458.2, SDHAF1, SYNE4, AC002116.1, ALKBH6, AC002116.2, CLIP3, THAP8, WDR62, AD000813.1, OVOL3, POLR2I, TBCB, AD001527.2, CAPNS1, AD001527.1, COX7A1, AC002984.1.
- chr19:37,007,857–37,130,368, 1 gene, copy number 7 (within-gene range 2–7): ZNF420.
- chr19:37,075,113–37,488,652, 16 genes, copy number 7: AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570.
- chr22:16,876,218–17,070,675, 14 genes, copy number 7: MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2.
- chr22:18,980,695–19,122,454, 11 genes, copy number 6 (within-gene range 2–6): AC007326.3, DGCR5, AC000095.2, AC000095.1, FAM246C, CA15P1, DGCR2, Y_RNA, DGCR11, AC004461.1, AC004461.2.
- chr22:19,130,279–19,144,684, 1 gene, copy number 7 (within-gene range 2–7): ESS2.
- chr22:19,146,993–20,016,823, 34 genes, copy number 7: GSC2, LINC01311, SLC25A1, CLTCL1, AC000072.1, AC000081.1, AC000081.2, KRT18P62, HIRA, C22orf39, RN7SL168P, MRPL40, AC000068.1, UFD1, AC000068.3, AC000068.2, CDC45, AC000082.1, CLDN5, LINC00895, AC000077.1, AC000067.1, SEPTIN5, AC000093.1, GP1BB, TBX1, GNB1L, AC000089.1, RTL10, TXNRD2, AC000078.1, COMT, MIR4761, ARVCF.
- chr22:22,988,263–23,784,316, 39 genes, copy number 5: AC245054.2, AC245054.1, RSPH14, GNAZ, Metazoa_SRP, U7, RAB36, BCR, BCRP8, RN7SL263P, FBXW4P1, AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2, LINC01659, AP000344.1, FAM230I, AP000345.3, LINC02557, PCAT14, AP000345.1, IGLL1, AP000345.2, AP000346.4, DRICH1, AP000346.3, AP000346.1, GUSBP11, AP000346.2, ASLP1, AP000347.1, RGL4, ZNF70, VPREB3, C22orf15, CHCHD10, MMP11.

Autosomal genes at a single copy (total copy number 1): 713. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
